Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3GV, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3GV-01A (Primary Tumor).

[page 1 of 2]
	11/30/11	

Pathology
Port

Pathology
Fax:

DOB:
Physician:

Sex: F

Collected:

Received:

Case type: Surgical Case

Accession:

DIAGNOSIS

(A) TOTAL THYROIDECTOMY

PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Left lobe
Multi-focal: No
Size = 1.9 cm
Extrathyroidal extension: Present, into soft tissue
Lymphovascular invasion: Absent
Resection Margins: Negative
Lymph nodes:

No tumor present in 1 lymph nodes (0/1)

(B) LEFT INFERIOR PARATHYROID:

Parathyroid tissue, no tumor present.

1CS-0-3
carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS C93.9
11/30/11

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY - A total thyroid with right lobe (2.5 x 2.2 x 1.1 cm), isthmus (1.2 x 1.5 x 0.5 cm) and left lobe (3.5 x 2.0 x 1.5 cm). The right lobe and isthmus are unremarkable. Within the soft tissues in the superior aspect of the isthmus are several possible lymph nodes. The left lobe contains a well-circumscribed solid mass at lower portion (1.9 x 1.5 x 1.0 cm). The nodule is confined to the thyroid.

SECTION CODE: A1, A2, representative sections from right lobe, superior to inferior; A3, possible lymph nodes; A4, section of isthmus; A5-A10, sections of left lobe from superior to inferior including the dominant nodule

(B) LEFT INFERIOR PARATHYROID, P/S RULE OUT - Received are two fragments of pale yellow and pink soft tissue fragments both measuring 0.3 cm in greatest dimension and has a combined weight of 0.0092 grams. The specimen is submitted entirely in B for frozen section evaluation. Touch preps are performed.

*FS/DX: PARATHYROID TISSUE PRESENT.

CLINICAL HISTORY

Papillary thyroid carcinoma.

SNOMED CODES

T-B6000, M-80503, T-C4200, M-00110,

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

[page 2 of 2]
Surgical Pathology Report

Department of Pathology,

DOB:
Physician:

Sex: F

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

Entire report and diagnosis completed by:

Surgical Pathology Report File under: Pathology	Page 2 of 2
---	-------------

Source: NCI Genomic Data Commons file e81b6174-25be-43fc-8a13-ae326ddd3317 (TCGA-EL-A3GV.96FB4A04-40F7-4E07-9FAD-334AFFEF232C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).